Gene-level copy-number profile of tumor specimen ALCH-B3HY-TTP1-A from ALCHEMIST case ALCH-B3HY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.6 years (25,414 days).
Specimen ALCH-B3HY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 768ea6ab-3971-4009-8118-d19f51c350cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3HY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/aaf6d82b-0342-43ef-8a8e-f95f925e6679

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 572; copy number 1: 2,878; copy number 2: 52,137; copy number 3: 2,697; copy number 4: 607; copy number 5: 15; copy number 23: 1.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,043,736–16,057,308, 1 gene: CLCNKB.
- chr1:24,919,345–24,919,416, 1 gene (within-gene range 0–2): MIR6731.
- chr2:96,938,923–96,939,203, 1 gene (within-gene range 0–2): Metazoa_SRP.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr7:155,399,922–155,401,782, 1 gene: AC008060.4.
- chr10:79,000,484–79,003,803, 1 gene (within-gene range 0–2): AL356753.1.
- chr15:25,176,832–25,191,497, 9 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12.
- chr15:25,206,262–25,250,940, 25 genes (within-gene range 0–2): SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:4,608,883–4,615,027, 1 gene: UBALD1.
- chr16:29,113,050–29,331,304, 4 genes (within-gene range 0–2): AC009093.8, AC009093.10, AC009093.2, AC009093.7.
- chr16:68,367,325–68,370,262, 1 gene (within-gene range 0–2): AC099521.2.
- chr19:19,254,748–19,273,369, 2 genes (within-gene range 0–2): AC138430.1, HAPLN4.
- chr19:19,264,364–19,273,391, 1 gene: TM6SF2.
- chr21:43,322,417–43,366,566, 3 genes: LINC00322, LINC01679, AP001046.1.
- chr21:43,465,309–43,467,298, 1 gene (within-gene range 0–23): AP001048.1.
- chr22:18,997,138–18,997,595, 1 gene (within-gene range 0–1): AC007326.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr12:46,183,063–47,079,959, 14 genes, copy number 5 (within-gene range 2–5): SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2.
- chr21:43,461,960–43,479,534, 1 gene, copy number 23 (within-gene range 0–23): LINC00313.

Autosomal genes at a single copy (total copy number 1): 543. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
